Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WM, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WM-01A (Primary Tumor).

ICD0-3
Astrocytoma, grade III 7/40/13
Site Brain, supratentorial NOS
C71.0
JW 8/12/13

Translation

diffuse astrocytic tumor of high mitotic activity
No necrosis and no microvascular proliferation

No IDH mutation

No 1p/19q loss

All together this tumor is still classified astrocytoma

Diagnosis

Anaplastic Astrocytoma WHO grade III

Untranslated full report
is housed at the BCR.

Source: NCI Genomic Data Commons file f64a7dbe-eea4-41fd-a4f4-dac33f7a5b6b (TCGA-S9-A6WM.481CC0B0-251F-436D-9330-A79BE83586B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).